Somatic mutation profile of tumor specimen BLGSP-71-17-00357-01B (aliquot BLGSP-71-17-00357-01B-09E-A77S-33) from CGCI case BLGSP-71-17-00357, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.9 years (25,523 days).
Specimen BLGSP-71-17-00357-01B: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c7ae034-7fd1-4914-8865-7ee3a52fab3c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-17-00357-99A (Granulocytes), aliquot BLGSP-71-17-00357-99A-01D-A77S-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a17a3e8-18e4-4663-a2a9-812d3b94e1b2

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 5'UTR 3, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ID3 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65800769, COSV65801494; called by muse, varscan2
- TENM3 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV69307146; called by muse, mutect2, varscan2
- WNK1 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 199/586 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60026815, COSV60033505; called by muse, mutect2, varscan2
- ADAMTS12 | c.2617A>G p.R873G | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ID3 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SMARCA4 | c.3674_3691del p.D1225_Q1230del | In Frame Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- DSEL | c.2319G>A p.R773= | Silent (SNP) | VAF 243/732 reads (33%) | catalogued as COSV59491805; called by muse, mutect2, varscan2
- H2BC12 | c.219C>T p.R73= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1253903745; called by muse, mutect2, varscan2
- SCN10A | c.2820G>A p.Q940= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- MYC | chr8:127735661 A>C | 5'Flank (SNP) | VAF 59/147 reads (40%) | catalogued as rs999667425; called by muse, mutect2, varscan2
- MYC | chr8:127736045 del A | 5'Flank (DEL) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- MYC | c.-491A>G | 5'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- MYC | c.-329G>A | 5'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as COSV104388183, COSV52378269; called by muse, mutect2, varscan2
- MYC | c.-175G>C | 5'UTR (SNP) | VAF 34/68 reads (50%) | catalogued as COSV104388825, COSV104388900, COSV52376773; called by muse, varscan2
